Gene-level copy-number profile of tumor specimen TCGA-UF-A7JA-01A from TCGA case TCGA-UF-A7JA, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cheek mucosa; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 66.0 years (24,121 days).
Specimen TCGA-UF-A7JA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.ea4694eb-8ff1-449e-9835-036e0cc7ea3e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UF-A7JA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0a194b4f-dbf5-4fd4-9daf-b6ebe5d56def

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 96; copy number 1: 13,688; copy number 2: 38,730; copy number 3: 5,622; copy number 4: 1,085; copy number 5: 379; copy number 6: 32; copy number 7: 5; copy number 8: 42; copy number 9: 22; copy number 10: 12; copy number 11: 4; copy number 13: 9; copy number 20: 52; copy number 26: 12; copy number 34: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-UF-A7JA-01A-12D-A34I-01): tumor purity 0.25, ploidy 3.4, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 96 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,898,423–141,208,376, 4 genes: LRRC57P1, Y_RNA, RNU6-904P, RPS16P3.
- chr4:185,585,444–185,956,652, 1 gene (within-gene range 0–2): SORBS2.
- chr4:185,709,873–190,092,279, 86 genes (broad region; genes not listed).
- chr11:80,653,429–81,431,520, 5 genes: ARL6IP1P3, LINC02720, AP003398.1, AP003398.2, AP003464.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 589 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:134,597,801–150,873,554, 261 genes, copy number 5–26 (broad region; genes not listed).
- chr3:150,870,376–150,941,743, 2 genes, copy number 5 (within-gene range 4–5): MINDY4B, AC020636.2.
- chr3:161,104,696–161,821,908, 11 genes, copy number 5 (within-gene range 3–5): NMD3, AC108738.1, EEF1GP4, PSMC1P7, SPTSSB, LINC02067, AC112491.1, RPL23AP42, OTOL1, AC112770.1, AC131211.1.
- chr3:164,171,471–173,336,965, 132 genes, copy number 5 (broad region; genes not listed).
- chr7:52,165,235–53,574,555, 12 genes, copy number 6: AC079763.1, AC006320.1, AC006459.1, SGO1P2, AC074397.1, POM121L12, HAUS6P1, RNF138P2, RNU1-14P, RN7SKP218, AC009468.2, AC009468.1.
- chr11:68,870,664–71,252,577, 61 genes, copy number 13–20 (broad region; genes not listed).
- chr13:70,564,267–71,914,178, 9 genes, copy number 7–10: AL445264.1, MTCL1P1, LINC00348, RABEPKP1, DACH1, H3P36, RPL21P109, RPL35AP31, RPS10P21.
- chr13:72,567,213–73,995,056, 22 genes, copy number 10–34: AL356754.2, AL356754.1, RPL21P110, RNU6-80P, MZT1, BORA, DIS3, PIBF1, RNU6-79P, PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392, KLF12, AL138713.1, AL159972.1.
- chr13:75,109,587–75,935,132, 16 genes, copy number 6: RNU6-38P, SSR1P2, CTAGE11P, LINC01078, TBC1D4, AL139230.1, COMMD6, UCHL3, AL137782.1, LMO7-AS1, LMO7, AL137244.1, FAM204CP, LMO7DN, LMO7DN-IT1, LINC00561.
- chr18:28,638,714–29,650,440, 8 genes, copy number 6–11: AC090365.1, ARIH2P1, AC023932.1, RNU6-408P, AC105245.1, AC074237.1, AC117569.1, AC117569.2.
- chr20:12,243,308–17,226,146, 55 genes, copy number 5: AL109838.1, AL136460.1, PA2G4P2, LINC01722, AL078623.1, AL133331.1, LINC01723, SPTLC3, AL109983.1, ISM1, ISM1-AS1, AL050320.1, AL121782.1, TASP1, GAPDHP2, ESF1, NDUFAF5, SEL1L2, RNU6-278P, MACROD2, RPS3P1, AIMP1P1, RN7SL864P, FLRT3, RNU6-228P, AL121582.1, RNF11P2, MACROD2-IT1, RPS10P2, MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P, RNA5SP475, AL121584.1, ENSAP1, AL079338.1, AL161941.1, PPIAP17, KIF16B, AL049794.1, AL049794.2, RPLP0P1, Y_RNA, AL135938.1, AL034428.1, SNRPB2, OTOR, AL121892.1, U3, RNU6-27P, AL359511.1, RNU1-131P, AL359511.2, AL359511.3.

Autosomal genes at a single copy (total copy number 1): 12,536. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
